TCGA case TCGA-DX-A8BH — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/505dc15c-4f74-43de-8eaf-32b7d7515edb

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 86 years; Vital status: Dead; Days to death: 439 days (1.2 years).

Diagnoses (3)
1. Undifferentiated sarcoma (the primary disease): ICD-O-3 morphology code: 8805/3; ICD-10 code: C49.6; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of trunk, NOS; Classification of tumor: primary; Age at diagnosis: 87.0 years (31,770 days); Year of diagnosis: 2013; Metastasis at diagnosis: No Metastasis; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 4; Tumor length measurement: 9.7; Tumor width measurement: 8.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved; Necrosis percent: 10; Necrosis present: Yes; Tumor depth descriptor: Deep.
2. Melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Thorax, NOS; Classification of tumor: Prior primary; Age at diagnosis: 83.0 years (30,317 days); Days to diagnosis: -1,453 days (-4.0 years).
3. Metastasis of diagnosis 1 (Undifferentiated sarcoma), site: Pleura, NOS. Age at diagnosis: 87.7 years (32,042 days); Days to diagnosis: 272 days; Prior treatment: Yes; Tumor focality: Multifocal.
   Pathology details: Measurement type: Radiologic; Tumor burden: 31.7.

Follow-up (3 entries)
- Days to follow up: 102 days; Disease response: Tumor Free.
- Day 272 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Pleura, NOS; Days to progression: 272 days; Discontiguous lesion count: 4.
- Days to follow up: 439 days (1.2 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DX-A8BH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 400 mg.
  Slide TCGA-DX-A8BH-01A-01-TSA: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DX-A8BH-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DX-A8BH-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 270 mg.
  Slide TCGA-DX-A8BH-11A-04-TSD: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free.
- Primary pathology: Histologic diagnosis: Pleomorphic 'MFH' / Undifferentiated pleomorphic sarcoma; Margin status: Positive; Tumor total necrosis: <10% (focal necrosis); Disease multifocal indicator: No; Locoregional recurrence indicator: No; Metastatic disease confirmed: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Superficial Trunk - Abdominal wall.
- Primary pathology, Tumor sizes, Tumor size: Lesion pathologic width: 8; Lesion pathologic depth: 4.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease.
- Drug treatment: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 280; Pharmaceutical therapy drug name: Gemcitabine; Pharmaceutical treatment ongoing indicator: Yes.
- Drug treatment, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Chest wall; Other malignancy histological type: Melanoma.
- Other malignancy form, Surgery: Other malignancy surgery type: Wide excision.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 439 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 439 days; disease-free interval: event (new tumor event after initially disease-free), 272 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 272 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DX-A8BH-01A-11D-A37B-01): tumor purity 0.43, ploidy 3.01, whole-genome doublings 1.
